Somatic mutation profile of tumor specimen TCGA-LN-A4A6-01A (aliquot TCGA-LN-A4A6-01A-11D-A27G-09) from TCGA case TCGA-LN-A4A6, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 65.7 years (24,011 days).
Specimen TCGA-LN-A4A6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45ab8233-c345-4b22-b345-bae79ece71bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A4A6-10A (Blood Derived Normal), aliquot TCGA-LN-A4A6-10A-01D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb47cdd7-dcd9-4682-896b-288f0e30749b

The open-access MAF lists 112 somatic variants for this specimen: 88 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 23, Nonsense Mutation 6, Frame Shift Ins 5, In Frame Del 1, 3'UTR 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 162/297 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CACNA2D1 | c.2843G>C p.S948T (on ENST00000356253 / NM_001366867.1; = p.S936T on NM_000722.4) | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.124); catalogued as rs1302167005, COSV62371367; called by muse, mutect2, varscan2
- CC2D2A | c.2987T>C p.I996T | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs754327317; called by muse, mutect2, varscan2
- CDC42BPG | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs753090372, COSV104418042; called by muse, varscan2
- CNGA3 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.133); catalogued as rs367575427; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPG1 | c.1249A>G p.I417V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.833); catalogued as rs762084251; called by muse, mutect2, varscan2
- CSMD3 | c.9265C>T p.H3089Y (on ENST00000297405 / NM_001363185.1; = p.H2920Y on NM_052900.3) | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs754162249, COSV52252059, COSV52262522; called by muse, mutect2, varscan2
- DHRSX | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as rs149133886, COSV58130209; called by muse, mutect2, varscan2
- DNAH5 | c.3426A>C p.K1142N | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV99445894; called by muse, mutect2, varscan2
- ENTR1 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.521); catalogued as rs763112506; called by muse, mutect2, varscan2
- ETV5 | c.1471G>A p.A491T | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs773704999; called by muse, mutect2, varscan2
- EXOC3L1 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs775635066, COSV99333329; called by muse, mutect2, varscan2
- GUSB | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs746475728, COSV59221302; called by muse, mutect2, varscan2
- H3C4 | c.340C>A p.H114N | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV61912129; called by muse, mutect2, varscan2
- KIDINS220 | c.2290C>T p.Q764* | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | catalogued as COSV56751851; called by muse, mutect2, varscan2
- KIF1A | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1469297168; called by muse, mutect2, varscan2
- MAGEC3 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs756867913, COSV68924037; called by mutect2, varscan2
- MAP4K5 | c.766A>G p.I256V | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs923529728, COSV50153978; called by muse, mutect2, varscan2
- NID1 | c.2117G>A p.R706Q | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs759141799, COSV51618836; called by muse, mutect2, varscan2
- NRP2 | c.2257G>T p.E753* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as rs753078349; called by muse, mutect2, varscan2
- OCIAD1 | c.696dup p.E233Rfs*13 | Frame Shift Ins (INS) | VAF 18/38 reads (47%) | catalogued as rs768679897; called by mutect2, varscan2
- PRDX6 | c.304A>G p.I102V | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV61165699; called by muse, mutect2, varscan2
- ROCK1 | c.2612A>C p.N871T | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs767267219, COSV67695859; called by muse, mutect2, varscan2
- SEBOX | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.22); catalogued as COSV99411960; called by muse, mutect2, varscan2
- SLC12A3 | c.2329C>T p.R777W | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs748994629; called by muse, mutect2, varscan2
- SLC18A2 | c.1139dup p.N380Kfs*81 | Frame Shift Ins (INS) | VAF 15/55 reads (27%) | catalogued as rs1182963631; called by mutect2, pindel, varscan2
- STAC | c.755G>T p.R252L | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as COSV56207282; called by muse, mutect2, varscan2
- UTP4 | c.1465C>G p.L489V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV58733719; called by muse, mutect2, varscan2
- VTCN1 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.067); catalogued as rs767710032; called by muse, mutect2, varscan2
- ZNF326 | c.1601A>G p.N534S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs1351556631; called by muse, mutect2, varscan2
- ZNF354A | c.1790A>G p.Y597C | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs775196494; called by muse, mutect2, varscan2
- ZNF780B | c.430A>G p.I144V | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.891); catalogued as COSV99665637; called by muse, mutect2, varscan2
- ZNF99 | c.1500G>T p.K500N | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV68055625; called by muse, mutect2, varscan2
- AHNAK | c.4513G>A p.D1505N | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- ANO3 | c.1275T>A p.N425K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- CASP5 | c.131C>A p.S44Y | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CCDC18 | c.49A>G p.S17G | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.14); called by muse, mutect2
- CCZ1 | c.446A>G p.N149S | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- CDKL4 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLDN18 | c.198T>A p.Y66* | Nonsense Mutation (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- CNTN5 | c.2568T>G p.N856K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COQ5 | c.268A>G p.I90V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- CPT1C | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- CSMD3 | c.445T>G p.S149A | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.082); called by muse, mutect2
- DPH2 | c.94G>A p.V32M | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2
- EIF3K | c.442A>T p.I148F | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- EPHB2 | c.1105_1125del p.R369_C375del | In Frame Del (DEL) | VAF 12/31 reads (39%) | called by mutect2, pindel
- ERV3-1 | c.590G>T p.C197F | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ERV3-1 | c.589T>C p.C197R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- FAT2 | c.1838A>G p.N613S | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- FOLR3 | c.389T>G p.L130R | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- GRHL2 | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by mutect2, varscan2
- HGSNAT | c.1213G>T p.G405C | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- JAK1 | c.98A>T p.E33V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KIF20B | c.1366A>G p.I456V | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- KLKB1 | c.1668A>T p.K556N | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- LARP1 | c.1847T>C p.M616T (on ENST00000518297 / NM_033551.3; = p.M539T on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- LYST | c.1375G>C p.D459H | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); called by muse, mutect2
- MAGEC3 | c.1728+1G>C p.X576_splice | Splice Site (SNP) | VAF 17/27 reads (63%) | called by muse, mutect2, varscan2
- MAP2K1 | c.1080del p.F360Lfs*74 | Frame Shift Del (DEL) | VAF 32/72 reads (44%) | called by mutect2, pindel, varscan2
- MDC1 | c.1688T>A p.L563H | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- MRGPRF | c.179T>A p.V60E | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.333); called by muse, mutect2
- MROH2B | c.4340A>C p.K1447T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- MSRB1 | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); called by muse, mutect2
- NECAB1 | c.870A>G p.I290M | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- NSD1 | c.4787G>T p.C1596F | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR6K6 | c.837dup p.G280Wfs*39 (on ENST00000368144; = p.G256Wfs*39 on NM_001005184.1) | Frame Shift Ins (INS) | VAF 19/102 reads (19%) | called by mutect2, pindel, varscan2
- PDCD6IP | c.751A>G p.I251V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.95); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PDS5A | c.975G>A p.W325* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- PRAMEF8 | c.152C>T p.T51I | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- PTPN14 | c.3153dup p.A1052Cfs*25 | Frame Shift Ins (INS) | VAF 14/80 reads (18%) | called by mutect2, pindel, varscan2
- PXMP2 | c.477G>T p.W159C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RANBP2 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 38/268 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SENP7 | c.1103T>C p.L368P | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC2A4RG | c.1054A>T p.K352* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- SLC7A2 | c.1090A>G p.I364V | Missense Mutation (SNP) | VAF 45/76 reads (59%) | SIFT tolerated (0.16); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SLCO1C1 | c.300C>A p.S100R | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYCP2 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNJ1 | c.1945C>T p.L649F | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRNAU1AP | c.626A>G p.Y209C | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- TRPM7 | c.4985A>G p.Y1662C | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VTA1 | c.438A>T p.R146S | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- WDR36 | c.526A>G p.I176V | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- XPNPEP3 | c.396C>A p.S132R | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZCCHC2 | c.2074C>T p.Q692* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
- ZNF404 | c.181dup p.R61Kfs*4 | Frame Shift Ins (INS) | VAF 8/17 reads (47%) | called by mutect2, pindel, varscan2
- ZNF410 | c.907C>T p.H303Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF519 | c.578C>G p.S193C | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- ARL14EP | c.90T>A p.T30= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- ATP8B1 | c.2280T>C p.D760= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs1347681654; called by muse, mutect2
- CGNL1 | c.15C>T p.F5= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs765549295, COSV55565288; called by muse, mutect2, varscan2
- CHRM2 | c.939C>T p.G313= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs774236034; called by muse, mutect2, varscan2
- CKAP5 | c.1908A>G p.P636= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV56370052; called by muse, mutect2, varscan2
- CRKL | c.277C>T p.L93= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs1196824980; called by muse, mutect2, varscan2
- CYP19A1 | c.1251T>C p.N417= | Silent (SNP) | VAF 30/53 reads (57%) | called by muse, mutect2, varscan2
- FRMPD3 | c.5370C>T p.G1790= | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- GFRA3 | c.126C>T p.N42= | Silent (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
- MKNK2 | c.84A>T p.L28= | Silent (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- NCEH1 | c.1326G>A p.K442= (on ENST00000538775; = p.K402= on NM_020792.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/181 reads (24%) | called by muse, mutect2, varscan2
- NYAP2 | c.918C>T p.F306= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs533815234, COSV56016566; called by muse, mutect2
- OVGP1 | c.291C>T p.I97= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as rs373255062; called by muse, mutect2, varscan2
- PIGC | c.531A>G p.L177= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs756094179; called by muse, mutect2, varscan2
- PPP1R17 | c.39A>T p.S13= | Silent (SNP) | VAF 29/96 reads (30%) | called by muse, mutect2, varscan2
- RC3H2 | c.1278A>G p.P426= | Silent (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- SIAH1 | c.303G>A p.A101= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as rs768759254; called by muse, mutect2, varscan2
- SLC35E4 | c.780C>T p.L260= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs1434670680; called by muse, mutect2, varscan2
- TCHH | c.2982G>A p.E994= | Silent (SNP) | VAF 12/68 reads (18%) | called by muse, mutect2, varscan2
- TMTC2 | c.741A>G p.G247= | Silent (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- TOP1MT | c.1200C>G p.L400= | Silent (SNP) | VAF 41/81 reads (51%) | catalogued as rs942018258; called by muse, mutect2, varscan2
- USH2A | c.5157C>T p.F1719= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100239074; called by muse, mutect2, varscan2
- WDR49 | c.117T>A p.I39= (on ENST00000308378 / NM_001366158.1; = p.I380= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*2852T>A | 3'UTR (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
